Somatic mutation profile of tumor specimen TARGET-20-PATHAE-04A (aliquot TARGET-20-PATHAE-04A-01D) from TARGET case TARGET-20-PATHAE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.6 years (6,062 days).
Specimen TARGET-20-PATHAE-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c709f696-7ea1-4383-aff4-50ff8f6a9a50.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATHAE-14A (Bone Marrow Normal), aliquot TARGET-20-PATHAE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f287811a-7fbf-4649-a742-febb5ab48853

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK2 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs746498471, COSV64492089; called by muse, mutect2, varscan2
- SETD2 | c.4486C>T p.R1496* | Nonsense Mutation (SNP) | VAF 9/144 reads (6%) | catalogued as COSV57434327; called by muse, mutect2
- U2AF1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs769567889, COSV52342800; called by muse, mutect2, varscan2
